Gene-level copy-number profile of tumor specimen TCGA-AO-A12D-01A from TCGA case TCGA-AO-A12D, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 43.2 years (15,774 days).
Specimen TCGA-AO-A12D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.83122683-8f67-481a-92f2-f60687a83ba3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A12D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3c9a6ff2-1c11-4d59-9b19-861035d0cd0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,133; copy number 2: 36,102; copy number 3: 5,569; copy number 4: 1,979; copy number 5: 379; copy number 6: 105; copy number 7: 394; copy number 8: 24; copy number 9: 3; copy number 12: 32; copy number 13: 9; copy number 19: 64; copy number 20: 16; copy number 52: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A12D-01A-11D-A111-01): tumor purity 0.3, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,030 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:200,027,614–200,177,420, 1 gene, copy number 7 (within-gene range 3–7): NR5A2.
- chr1:200,147,531–203,400,581, 109 genes, copy number 5–7 (broad region; genes not listed).
- chr1:204,346,776–205,532,793, 36 genes, copy number 5–7 (within-gene range 3–7): AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18.
- chr1:208,972,454–211,316,385, 45 genes, copy number 6: LINC01774, AC104465.1, AC092810.3, AC092810.2, AC092810.1, TFDP1P1, ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2, CAMK1G, LAMB3, MIR4260, HSD11B1-AS1, G0S2, HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25, SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3.
- chr1:212,168,207–212,446,379, 11 genes, copy number 5: AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1, AC092803.3, NENF.
- chr1:215,567,304–217,137,755, 8 genes, copy number 5–9: KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG.
- chr1:220,313,945–224,228,043, 79 genes, copy number 5–12 (broad region; genes not listed).
- chr1:225,465,021–231,819,244, 202 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr1:231,670,635–231,670,750, 1 gene, copy number 5: RNU5A-5P.
- chr4:72,965,178–74,589,481, 40 genes, copy number 6: RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1.
- chr4:75,194,867–76,112,802, 24 genes, copy number 7: AC093870.1, AC025244.1, AC025244.2, LINC02483, AC096759.1, AC096759.2, RCHY1, THAP6, ODAPH, CDKL2, G3BP2, Y_RNA, USO1, AC110615.1, RNU2-16P, PPEF2, NAAA, SDAD1, SDAD1-AS1, CXCL9, ART3, CXCL10, CXCL11, AC112719.1.
- chr4:91,603,275–91,904,335, 3 genes, copy number 5: AC110774.1, KRT19P6, AC093810.1.
- chr4:142,023,160–143,557,486, 19 genes, copy number 6: INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1, AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1.
- chr4:143,559,472–143,561,460, 1 gene, copy number 6: GUSBP5.
- chr4:144,111,039–146,642,474, 43 genes, copy number 5 (within-gene range 4–5): AC098588.3, AC098588.2, AC106871.1, KRT18P51, HHIP-AS1, HHIP, AC098588.1, ANAPC10, HSPD1P5, AC109811.1, AC109811.2, RN7SKP235, ABCE1, OTUD4, Y_RNA, RPS23P4, LINC02266, RTN3P1, AC079228.1, AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1, MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2, REELD1, AC097372.3, AC097372.1, SLC10A7, MIR7849, RNU1-44P, POU4F2.
- chr7:67,769,629–67,770,468, 1 gene, copy number 19: AC092648.1.
- chr7:69,330,698–69,401,303, 3 genes, copy number 12: MTCO2P25, MTCO1P25, RNU6-229P.
- chr7:71,779,491–76,074,963, 131 genes, copy number 7–20 (broad region; genes not listed).
- chr12:31,534,715–31,673,114, 7 genes, copy number 8: ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT.
- chr17:28,018,770–29,707,090, 115 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr17:29,639,627–29,645,847, 3 genes, copy number 7: AC104564.1, RNU6-920P, AC104564.5.
- chr17:39,200,283–40,381,838, 54 genes, copy number 19–52: RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2.
- chr17:48,377,262–48,606,414, 13 genes, copy number 19 (within-gene range 1–19): AC036222.2, U3, AC036222.1, Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A.
- chr21:18,561,265–19,134,423, 9 genes, copy number 13: MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1.
- chr22:40,044,817–41,998,221, 72 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,340. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
